Somatic mutation profile of tumor specimen TCGA-EC-A1QX-01A (aliquot TCGA-EC-A1QX-01A-31D-A16D-09) from TCGA case TCGA-EC-A1QX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 71.9 years (26,259 days).
Specimen TCGA-EC-A1QX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f98f3731-b1cc-4f4b-a228-1b72b1791c95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EC-A1QX-10A (Blood Derived Normal), aliquot TCGA-EC-A1QX-10A-01D-A16D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18daee2a-d3e3-41a5-82bf-bfc83945a9e2

The open-access MAF lists 781 somatic variants for this specimen: 584 protein-altering or splice-affecting, 177 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 416, Silent 177, Frame Shift Del 110, Nonsense Mutation 23, Frame Shift Ins 19, Intron 10, Splice Site 8, RNA 4, In Frame Del 4, Splice Region 3, 3'UTR 3, 5'Flank 2.

Variants (750 of 781; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD1 | c.1780+2T>G p.X594_splice | Splice Site (SNP) | VAF 15/71 reads (21%) | catalogued as rs1557054875, CS991289, COSV99497660; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP2A1 | c.2464dup p.R822Pfs*39 | Frame Shift Ins (INS) | VAF 16/75 reads (21%) | catalogued as rs751365374; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BCL10 | c.136del p.I46Yfs*24 | Frame Shift Del (DEL) | VAF 13/30 reads (43%) | catalogued as rs387906351; ClinVar: pathogenic; called by mutect2, varscan2
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 30/88 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, varscan2
- CYP17A1 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs104894154, CM063944, COSV64005017; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EIF1AX | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 18/94 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as COSV63309390, COSV63309515; called by muse, mutect2, varscan2
- ERBB2 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 14/76 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs1057519862, COSV54062926; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- GCDH | c.1173dup p.N392Efs*5 | Frame Shift Ins (INS) | VAF 18/63 reads (29%) | catalogued as rs754002357; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MFRP | chr11:119345563 del G | 5'Flank (DEL) | VAF 10/32 reads (31%) | catalogued as rs587776596, CD052468, COSV64129114; ClinVar: pathogenic; called by mutect2, pindel
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- PCDH15 | c.2487dup p.E830Rfs*54 | Frame Shift Ins (INS) | VAF 18/65 reads (28%) | catalogued as rs757027638; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.531T>G p.Y177* | Nonsense Mutation (SNP) | VAF 28/44 reads (64%) | hotspot (GDC flag); catalogued as rs878853012, COSV100909304, COSV64289866, COSV64296956; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1222400729, COSV52705120; called by muse, mutect2
- ABCA12 | c.3342G>A p.W1114* (on ENST00000272895 / NM_173076.3; = p.W796* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99790356; called by muse, mutect2
- ABCA13 | c.13234C>A p.L4412I | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV101291364, COSV68943465; called by muse, mutect2
- ABCA4 | c.573C>T p.F191= | Splice Region (SNP) | VAF 5/15 reads (33%) | catalogued as rs374454045; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA7 | c.5813T>C p.L1938P | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV99566027; called by muse, mutect2, varscan2
- ABCC10 | c.1511C>T p.A504V (on ENST00000372530 / NM_001198934.2; = p.A461V on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs543886430, COSV55084501; called by muse, mutect2, varscan2
- ABCC3 | c.998G>A p.S333N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV99559311; called by muse, mutect2, varscan2
- ABCC8 | c.1654A>G p.I552V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.262); catalogued as rs766577816, COSV100217365; called by muse, mutect2, varscan2
- ABCG8 | c.1468G>A p.G490S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.071); catalogued as rs769813197, COSV99699918; called by muse, mutect2, varscan2
- ABHD17C | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99358719; called by muse, mutect2, varscan2
- ACAP1 | c.1292C>A p.A431D | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99341743; called by muse, mutect2, varscan2
- ACBD3 | c.568del p.R190Gfs*43 | Frame Shift Del (DEL) | VAF 18/93 reads (19%) | catalogued as rs757016425; called by mutect2, varscan2
- ACSM3 | c.419G>A p.C140Y | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99184586; called by muse, mutect2, varscan2
- ACTR1A | c.998C>A p.P333H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99487921; called by muse, mutect2, varscan2
- ADAMTS13 | c.3574T>C p.C1192R | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52471176; called by muse, mutect2, varscan2
- ADAMTS6 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1442947114, COSV66862199; called by muse, mutect2
- ADCY1 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1363336078, COSV99812221; called by muse, mutect2, varscan2
- ADCY10 | c.3542del p.N1181Tfs*7 | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | catalogued as CM110788; called by mutect2, pindel, varscan2
- AHNAK | c.12649C>A p.L4217I | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs920534475, COSV99947943; called by muse, varscan2
- AK9 | c.5225C>T p.A1742V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV101413975; called by muse, mutect2
- AKAP11 | c.4436G>A p.G1479D | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as COSV99214016; called by muse, mutect2, varscan2
- AKAP13 | c.2902A>T p.I968F | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV100773964, COSV100774633; called by muse, mutect2, varscan2
- AKR7A2 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV99352068; called by muse, mutect2, varscan2
- ALLC | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.259); catalogued as COSV99377937; called by muse, mutect2, varscan2
- ANAPC13 | c.213del p.I72Lfs*48 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | catalogued as rs1559828949; called by mutect2, pindel, varscan2
- ANKRD17 | c.2237G>A p.R746H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1560584488, COSV100429317, COSV58220458; called by muse, mutect2, varscan2
- ANKRD39 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.994); catalogued as COSV100561042; called by muse, mutect2, varscan2
- ANKRD50 | c.2746G>A p.A916T | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs779926917, COSV101538986; called by muse, mutect2, varscan2
- ANO7 | c.1414G>T p.A472S (on ENST00000274979; = p.A418S on NM_001370694.2) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); catalogued as COSV99238620; called by muse, mutect2, varscan2
- ANO8 | c.2650G>A p.E884K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50174027; called by muse, mutect2, varscan2
- ARAP1 | c.95T>C p.L32P | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100501977; called by muse, mutect2, varscan2
- ARAP3 | c.3673C>A p.P1225T | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.879); catalogued as COSV99499830; called by muse, mutect2, varscan2
- ARFGEF2 | c.3647C>T p.A1216V | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.351); catalogued as COSV100904312; called by muse, mutect2, varscan2
- ARFGEF3 | c.1920A>C p.E640D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV99293810; called by muse, mutect2
- ARHGAP32 | c.5137G>A p.A1713T (on ENST00000310343 / NM_001378025.1; = p.A1364T on NM_014715.4) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100088072; called by muse, mutect2, varscan2
- ARHGEF12 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs141324681; called by muse, mutect2, varscan2
- ARHGEF26 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs368674648, COSV62844927; called by muse, mutect2, varscan2
- ARR3 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.435); catalogued as rs778493881, COSV57203793; called by muse, mutect2, varscan2
- ATF4 | c.406del p.Q136Rfs*3 | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | catalogued as rs770192882; called by mutect2, pindel, varscan2
- ATG3 | c.674A>T p.Q225L | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.232); catalogued as COSV99343897, COSV99344223; called by muse, mutect2, varscan2
- ATG7 | c.1968A>T p.Q656H | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100607409; called by muse, mutect2, varscan2
- ATP1A2 | c.3022C>T p.R1008W | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV63401929; called by mutect2, varscan2
- B3GAT3 | c.488A>T p.K163M | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV99605964; called by muse, mutect2, varscan2
- BRI3BP | c.638G>A p.S213N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.242); catalogued as COSV100413063, COSV58295875; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- C16orf78 | c.76A>G p.R26G | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100147785; called by muse, mutect2, varscan2
- C2CD2 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as rs746797812, COSV100297901; called by muse, mutect2, varscan2
- C7orf31 | c.358del p.S120Vfs*9 | Frame Shift Del (DEL) | VAF 19/89 reads (21%) | catalogued as rs750735753; called by mutect2, pindel, varscan2
- CANX | c.1305del p.F435Lfs*12 | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | catalogued as rs760711956; called by mutect2, varscan2
- CAPN9 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs536743386, COSV55230817; called by muse, mutect2, varscan2
- CARMIL2 | c.1759_1760del p.L587Vfs*4 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | catalogued as rs1370193840; called by pindel, varscan2
- CCDC120 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100900656; called by muse, mutect2, varscan2
- CCDC144A | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); catalogued as COSV100502010; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 36/124 reads (29%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC197 | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1379494504, COSV100113655; called by muse, mutect2, varscan2
- CCDC27 | c.1345C>G p.Q449E | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs145188556; called by muse, mutect2, varscan2
- CCDC39 | c.1045dup p.T349Nfs*2 | Frame Shift Ins (INS) | VAF 9/57 reads (16%) | catalogued as rs747980515; called by mutect2, pindel
- CCPG1 | c.2119T>C p.Y707H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99380444; called by muse, mutect2, varscan2
- CDC25A | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.077); catalogued as COSV100207519; called by muse, mutect2, varscan2
- CDH5 | c.2147C>T p.A716V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs760421733, COSV100439284; called by muse, varscan2
- CDR2 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.055); catalogued as COSV99193530; called by muse, mutect2
- CEBPA | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as CD1210607, COSV100204617; called by muse, mutect2, varscan2
- CERS1 | c.800C>T p.T267I | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99897276; called by muse, mutect2, varscan2
- CES5A | c.1475G>A p.W492* (on ENST00000290567 / NM_001143685.2; = p.W442* on NM_145024.3) | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99307667; called by muse, mutect2
- CFAP157 | c.1157A>G p.D386G | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as COSV100076925; called by muse, mutect2
- CFAP46 | c.6460A>G p.T2154A | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.63); catalogued as COSV99585014; called by muse, mutect2, varscan2
- CFAP74 | c.267G>T p.E89D | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.557); catalogued as rs780149453, COSV54575399, COSV99574324; called by muse, mutect2, varscan2
- CHD6 | c.296A>C p.K99T | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100498372; called by muse, mutect2
- CHST5 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.133); catalogued as COSV100292014, COSV60339764; called by muse, mutect2
- CHSY3 | c.2284A>G p.T762A | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as rs1440954114, COSV100519327; called by muse, mutect2, varscan2
- CLDN4 | c.497T>C p.V166A | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as rs782337604, COSV99936496; called by muse, mutect2, varscan2
- CLEC4M | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as rs760008267, COSV50216702; called by muse, mutect2, varscan2
- CLPTM1 | c.1847C>T p.T616I | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV100493809; called by muse, mutect2, varscan2
- CMTM5 | c.377del p.P126Rfs*55 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | catalogued as rs751921758; called by mutect2, pindel, varscan2
- CNEP1R1 | c.254T>A p.I85K (on ENST00000427478 / NM_001281789.1; = p.I102K on NM_153261.5) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV101208062; called by muse, mutect2, varscan2
- CNN2 | c.650G>A p.S217N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99566023; called by muse, mutect2
- CNRIP1 | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | catalogued as COSV99721238; called by muse, mutect2
- CNTN2 | c.497A>G p.Y166C | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs1474575005, COSV59347879; called by muse, mutect2, varscan2
- COA6 | c.181del p.A61Pfs*9 | Frame Shift Del (DEL) | VAF 12/65 reads (18%) | catalogued as rs1161604507; called by mutect2, pindel, varscan2
- COBL | c.2363C>T p.A788V | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99472899; called by muse, mutect2
- COIL | c.587del p.K196Rfs*13 | Frame Shift Del (DEL) | VAF 34/70 reads (49%) | catalogued as rs748995811; called by mutect2, varscan2
- COL14A1 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.545); catalogued as rs1379047536, COSV52868933, COSV99919557; called by muse, mutect2, varscan2
- COL24A1 | c.5125A>G p.S1709G | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100993482; called by muse, mutect2, varscan2
- COL27A1 | c.3625C>A p.P1209T | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.165); catalogued as COSV100621051; called by muse, mutect2, varscan2
- COL5A3 | c.1835C>A p.P612H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV99318790, COSV99319006; called by muse, mutect2, varscan2
- COL6A6 | c.4192G>T p.G1398* | Nonsense Mutation (SNP) | VAF 12/180 reads (7%) | catalogued as COSV100650363; called by muse, mutect2
- CPED1 | c.2837T>C p.L946P | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV60008850; called by muse, mutect2, varscan2
- CPPED1 | c.80G>T p.S27I | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as COSV99903270; called by muse, mutect2, varscan2
- CPSF2 | c.1654del p.I552Sfs*5 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | catalogued as rs758712860; called by mutect2, pindel, varscan2
- CREBBP | c.6310C>T p.R2104C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1489860615, COSV52112713; called by muse, mutect2, varscan2
- CRTAP | c.998A>G p.Q333R | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV100310123; called by muse, mutect2, varscan2
- CRYGB | c.251del p.P84Rfs*8 | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | catalogued as rs1559328208, COSV53679868; called by mutect2, pindel, varscan2
- CSF2RA | c.611A>G p.Q204R | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.372); catalogued as COSV100817790; called by muse, mutect2
- CSF2RB | c.1701del p.S568Afs*130 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs757082963; called by mutect2, pindel, varscan2
- CSN1S1 | c.294G>C p.K98N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1310476621, COSV99886787; called by muse, mutect2, varscan2
- CTNND2 | c.3311G>A p.G1104D | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100477733; called by muse, mutect2, varscan2
- CUL9 | c.273C>A p.H91Q | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99335531; called by muse, mutect2, varscan2
- CXCL14 | c.294G>A p.W98* (on ENST00000337225; = p.W86* on NM_004887.5) | Nonsense Mutation (SNP) | VAF 23/100 reads (23%) | catalogued as COSV100463641; called by muse, mutect2, varscan2
- CXCL8 | c.*5del | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs201169323; called by mutect2, pindel, varscan2
- CYFIP1 | c.2828G>A p.G943D | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.081); catalogued as COSV100488365; called by muse, mutect2, varscan2
- CYP19A1 | c.787del p.R263Dfs*20 | Frame Shift Del (DEL) | VAF 18/119 reads (15%) | catalogued as COSV53056524; called by mutect2, pindel, varscan2
- DACT1 | c.2119G>A p.A707T | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs755263046, COSV60019157; called by muse, mutect2, varscan2
- DAGLA | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.18); catalogued as rs866641215, COSV57196555; called by muse, mutect2
- DALRD3 | c.1555C>T p.Q519* (on ENST00000341949 / NM_001009996.3; = p.Q352* on NM_018114.5) | Nonsense Mutation (SNP) | VAF 21/57 reads (37%) | catalogued as COSV100482848; called by muse, mutect2, varscan2
- DDX46 | c.2893G>A p.A965T | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as rs867777664, COSV62800209; called by muse, mutect2, varscan2
- DDX60 | c.3145G>A p.E1049K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs1231674282, COSV67096835; called by muse, mutect2, varscan2
- DENND2B | c.437G>C p.G146A | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.024); catalogued as rs1050952138, COSV58205169; called by muse, mutect2, varscan2
- DENND6B | c.400G>A p.V134M | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs747816538, COSV101306084; called by muse, mutect2, varscan2
- DEPTOR | c.1007A>G p.D336G | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99638749; called by muse, mutect2, varscan2
- DHX16 | c.2606T>C p.V869A | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as COSV99528035; called by muse, mutect2, varscan2
- DLGAP4 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.309); catalogued as COSV100211366; called by muse, mutect2, varscan2
- DLX2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.544); catalogued as COSV99308587; called by muse, mutect2, varscan2
- DMPK | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs372902369; called by muse, mutect2, varscan2
- DMXL2 | c.6736C>T p.P2246S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99196483; called by muse, mutect2, varscan2
- DNAH10 | c.2882T>C p.L961P (on ENST00000409039; = p.L900P on NM_207437.3) | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs199754524, COSV101292332, COSV68997884; called by muse, mutect2, varscan2
- DNER | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.129); catalogued as rs780759032, COSV100519278; called by muse, mutect2, varscan2
- DNMT3A | c.2012C>T p.T671M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV53066939; called by muse, mutect2, varscan2
- DOCK4 | c.4889G>A p.R1630H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.976); catalogued as rs765468990, COSV101447884; called by muse, varscan2
- DOCK8 | c.3339del p.F1113Lfs*2 | Frame Shift Del (DEL) | VAF 24/86 reads (28%) | catalogued as rs748134881; called by mutect2, varscan2
- DST | c.1588C>A p.L530I (on ENST00000361203 / NM_001374722.1; = p.L204I on NM_001723.6) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV99757317; called by muse, mutect2, varscan2
- DUSP5 | c.443A>G p.Q148R | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.057); catalogued as COSV100851906; called by muse, mutect2, varscan2
- DYNC1I2 | c.105del p.E36Kfs*34 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | catalogued as rs755197346; called by mutect2, varscan2
- ECM1 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as rs374399587; called by muse, mutect2, varscan2
- EGFL8 | c.161G>A p.S54N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV100246976; called by muse, mutect2, varscan2
- EGLN2 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); catalogued as COSV100393780; called by muse, mutect2, varscan2
- EHMT2 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1187974630, COSV100977216; called by muse, mutect2, varscan2
- EIF2D | c.1615G>A p.G539R | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99662856; called by muse, mutect2, varscan2
- EIF5 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.155); catalogued as rs1368901390, COSV99384880; called by muse, mutect2, varscan2
- ELN | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as rs142438174, COSV52712498; called by muse, mutect2, varscan2
- EPC1 | c.1932G>T p.Q644H | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV99553034; called by muse, mutect2
- EPC2 | c.2291C>T p.A764V | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99308826; called by muse, mutect2, varscan2
- EVA1C | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs140051684; called by muse, mutect2, varscan2
- EVI5 | c.1222del p.M408* | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs760182064; called by mutect2, varscan2
- F5 | c.3088C>T p.R1030* | Nonsense Mutation (SNP) | VAF 9/54 reads (17%) | catalogued as rs780253174, CM032892, COSV63120947; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | catalogued as rs766589051; called by mutect2, pindel, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | catalogued as rs751966944; called by mutect2, pindel, varscan2
- FAM120B | c.745T>C p.S249P | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV99379479; called by muse, mutect2, varscan2
- FAM13A | c.2992G>T p.E998* | Nonsense Mutation (SNP) | VAF 24/92 reads (26%) | catalogued as COSV99983913; called by muse, mutect2, varscan2
- FAM171A1 | c.1627C>T p.R543* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | catalogued as COSV65313561; called by muse, mutect2, varscan2
- FAM91A1 | c.529A>G p.I177V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.949); catalogued as rs992277555, COSV100593640; called by muse, mutect2, varscan2
- FANCA | c.554T>C p.L185P | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV101224891; called by muse, mutect2
- FARP2 | c.821G>T p.S274I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99884807; called by muse, mutect2, varscan2
- FBP2 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs748612104, COSV64695871; called by muse, mutect2, varscan2
- FBXO21 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100401770, COSV57974698; called by muse, mutect2
- FCRL5 | c.2347C>A p.L783M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); catalogued as COSV100709233, COSV62520524; called by muse, mutect2, varscan2
- FDXR | c.848C>T p.T283M (on ENST00000293195 / NM_024417.5; = p.T289M on NM_004110.6) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as rs200068906, COSV99501088; called by muse, varscan2
- FGF5 | c.441del p.G148Efs*45 | Frame Shift Del (DEL) | VAF 19/74 reads (26%) | catalogued as rs35667286; called by mutect2, pindel, varscan2
- FNDC1 | c.2104dup p.H702Pfs*47 | Frame Shift Ins (INS) | VAF 12/54 reads (22%) | catalogued as rs751720114; called by mutect2, pindel, varscan2
- FOCAD | c.4562G>A p.S1521N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (1); PolyPhen probably damaging (0.993); catalogued as rs367988293, COSV58102723; called by muse, mutect2, varscan2
- FOXD4 | c.64G>T p.G22W | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV100071011; called by muse, mutect2
- FOXN3 | c.659C>T p.T220I | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as COSV99726665; called by muse, mutect2, varscan2
- FRMPD3 | c.3539G>A p.C1180Y | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1379229727, COSV99346489; called by muse, mutect2, varscan2
- GABRE | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs762784398, COSV100944306; called by muse, mutect2, varscan2
- GBE1 | c.1963G>A p.A655T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs1227807234, COSV101450176; called by muse, mutect2, varscan2
- GBP3 | c.1753del p.T585Pfs*9 | Frame Shift Del (DEL) | VAF 30/110 reads (27%) | catalogued as rs548474277; called by mutect2, varscan2
- GBP6 | c.611T>C p.L204S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100969567; called by muse, mutect2, varscan2
- GCN1 | c.1808G>A p.G603E | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.95); PolyPhen benign (0.041); catalogued as COSV100325460; called by muse, mutect2, varscan2
- GEMIN5 | c.3178G>A p.A1060T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.412); catalogued as rs1337840295, COSV99594007, COSV99594011; called by muse, mutect2, varscan2
- GEMIN7 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1162811503, COSV99541618; called by muse, mutect2, varscan2
- GGT7 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as COSV100322000; called by muse, mutect2, varscan2
- GK2 | c.56G>A p.G19D | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62627937; called by muse, mutect2, varscan2
- GLG1 | c.2763A>G p.I921M | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52677160; called by muse, mutect2, varscan2
- GML | c.365T>C p.M122T | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV55277352; called by muse, mutect2, varscan2
- GPR65 | c.371del p.F124Sfs*2 | Frame Shift Del (DEL) | VAF 18/66 reads (27%) | catalogued as rs770829884; called by mutect2, varscan2
- GREB1 | c.5690C>T p.A1897V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99303083; called by muse, mutect2, varscan2
- GRM4 | c.1930A>T p.I644F | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV100946321; called by muse, mutect2
- GSAP | c.1029C>A p.D343E | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV99990256; called by muse, mutect2
- GTF2IRD2 | c.1473del p.L493Sfs*6 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | catalogued as COSV63100325; called by mutect2, pindel, varscan2
- GTF3C4 | c.1714T>A p.Y572N | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100936031; called by muse, mutect2, varscan2
- HCCS | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372501217, COSV58239558; called by mutect2, varscan2
- HCRTR1 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs1361829354, COSV65485430; called by muse, mutect2, varscan2
- HECTD4 | c.10762G>A p.A3588T | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101107770; called by muse, mutect2
- HECW1 | c.1996G>A p.G666R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); catalogued as rs752558345, COSV67822233, COSV67824868; called by muse, mutect2
- HECW2 | c.722A>G p.N241S | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.191); catalogued as rs368745543; called by muse, mutect2, varscan2
- HEMGN | c.118C>T p.L40F | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99412423; called by muse, mutect2
- HERC6 | c.1628T>G p.I543S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.15); catalogued as COSV99986734; called by muse, varscan2
- HIC2 | c.1627A>G p.T543A | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV101335598; called by muse, mutect2, varscan2
- HID1 | c.1453C>T p.L485F | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100586011; called by muse, mutect2, varscan2
- HINFP | c.1366T>C p.S456P | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100640858; called by muse, mutect2, varscan2
- HNRNPA3 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); catalogued as COSV101182935; called by muse, mutect2, varscan2
- HSPA4L | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs931852692, COSV99613122; called by muse, mutect2, varscan2
- HSPA9 | c.154A>G p.K52E | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.271); catalogued as COSV99785540; called by muse, mutect2, varscan2
- IDE | c.1706del p.L569Cfs*45 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs771790236; called by mutect2, varscan2
- IDH1 | c.492G>T p.K164N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.082); catalogued as COSV100576913; called by muse, mutect2, varscan2
- IGDCC4 | c.862G>T p.D288Y | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61536378; called by muse, mutect2, varscan2
- IGSF9 | c.154del p.L52Cfs*79 | Frame Shift Del (DEL) | VAF 20/78 reads (26%) | catalogued as rs753928344; called by mutect2, pindel, varscan2
- IL5RA | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV56526531, COSV99843065; called by muse, mutect2, varscan2
- IMPG2 | c.2189C>A p.S730Y | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.176); catalogued as COSV99515726; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs760925109; called by mutect2, pindel
- IQSEC2 | c.3232G>A p.E1078K (on ENST00000642864 / NM_001111125.3; = p.E873K on NM_015075.2) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100944946; called by muse, mutect2, varscan2
- ITPR1 | c.5063G>A p.G1688D (on ENST00000354582; = p.G1673D on NM_002222.7) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.67); PolyPhen probably damaging (1); catalogued as COSV100231711; called by muse, mutect2, varscan2
- JMJD1C | c.5450T>A p.V1817E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV100550636; called by muse, mutect2, varscan2
- KAT2A | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV99863589; called by muse, mutect2
- KAT2B | c.1374G>A p.M458I | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.041); catalogued as COSV55433453, COSV99769427; called by muse, mutect2, varscan2
- KCNK13 | c.608C>T p.T203I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV99965766; called by muse, varscan2
- KCNK13 | c.655A>G p.I219V | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs111667500, COSV56412036; called by muse, varscan2
- KDM2B | c.3889C>T p.H1297Y | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.142); catalogued as rs782596102, COSV100997452; called by muse, mutect2
- KDR | c.446C>A p.P149Q | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99817947; called by muse, mutect2, varscan2
- KEL | c.1771+1G>A p.X591_splice | Splice Site (SNP) | VAF 7/35 reads (20%) | catalogued as rs869025768, CS148139, COSV100787116; called by muse, mutect2
- KIAA1109 | c.13434G>A p.M4478I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV99165471; called by muse, mutect2, varscan2
- KIAA1614 | c.3256G>A p.A1086T | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.153); catalogued as COSV100799813; called by muse, mutect2, varscan2
- KLC2 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100270768; called by muse, mutect2, varscan2
- KLHL12 | c.80G>T p.R27M | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100935715; called by muse, mutect2, varscan2
- KLHL34 | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV101069943; called by muse, mutect2, varscan2
- KLK1 | c.758G>A p.W253* | Nonsense Mutation (SNP) | VAF 6/71 reads (8%) | catalogued as rs938985509, COSV100032775; called by muse, mutect2
- KMT2B | c.7700G>A p.R2567H | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV99495198; called by muse, mutect2, varscan2
- KRT4 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs370759790, COSV53406267; ClinVar: likely benign; called by muse, mutect2, varscan2
- KRTAP10-1 | c.83A>T p.E28V | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV100554129; called by muse, mutect2, varscan2
- KSR2 | c.1729G>T p.D577Y | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV100195515, COSV56685400; called by muse, mutect2, varscan2
- LAMA2 | c.7452-1G>T p.X2484_splice | Splice Site (SNP) | VAF 9/35 reads (26%) | catalogued as COSV101370552; called by muse, mutect2, varscan2
- LAMB3 | c.1626G>T p.E542D | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.656); catalogued as COSV100620392; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LARP7 | c.*9del | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as rs746633076; called by mutect2, varscan2
- LBR | c.1030C>T p.L344F | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99687474; called by muse, mutect2
- LGR4 | c.2530G>A p.D844N | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs575009262, COSV100156607, COSV58726881; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 26/55 reads (47%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LRFN2 | c.1508C>T p.T503M | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs762355650, COSV57825240; called by muse, mutect2, varscan2
- LRP1 | c.4270C>T p.R1424C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1238735535, COSV54520939, COSV99676189; called by muse, mutect2, varscan2
- LRRC7 | c.793G>T p.G265W (on ENST00000651989 / NM_001370785.2; = p.G232W on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50453892; called by muse, mutect2, varscan2
- LRRC8E | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV100142983; called by muse, mutect2, varscan2
- LRRIQ4 | c.942T>G p.H314Q | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as COSV100540279; called by muse, mutect2
- LRRK1 | c.5369G>A p.R1790Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs749481480, COSV99440714; called by muse, mutect2, varscan2
- LSR | c.634dup p.D212Gfs*20 | Frame Shift Ins (INS) | VAF 9/37 reads (24%) | catalogued as rs1350309519; called by mutect2, pindel, varscan2
- LY75 | c.2639G>A p.W880* | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as COSV99716571; called by muse, mutect2, varscan2
- M1AP | c.1237del p.L413Cfs*40 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | catalogued as rs1558644796; called by mutect2, pindel, varscan2
- MAEL | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100901860, COSV63306129; called by muse, mutect2
- MAGI2 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1470111212, COSV62670057; called by muse, mutect2, varscan2
- MAP1A | c.6193del p.R2065Vfs*5 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | catalogued as COSV55811343; called by mutect2, pindel, varscan2
- MAP3K19 | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); catalogued as rs373802326; called by muse, mutect2, varscan2
- MAP7D3 | c.1042G>C p.V348L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.042); catalogued as COSV100286408; called by mutect2, varscan2
- MATR3 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as COSV100735238; called by muse, mutect2, varscan2
- MBOAT2 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs756373257, COSV60007885; called by muse, mutect2, varscan2
- MCAT | c.896C>A p.S299Y | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99295703; called by muse, mutect2
- MDC1 | c.4901C>T p.T1634I | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs770716446, COSV100902867; called by muse, mutect2, varscan2
- MDFIC | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV99995202; called by muse, mutect2, varscan2
- ME1 | c.134C>A p.P45Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100866553; called by muse, mutect2, varscan2
- MEF2C | c.93G>T p.K31N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057518382, COSV100425487; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as rs780635289; called by mutect2, varscan2
- MGRN1 | c.1376C>A p.S459Y | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99274395; called by muse, mutect2
- MGST2 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs141597730; called by muse, mutect2, varscan2
- MICOS13 | c.150del p.A51Pfs*39 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs751944867; called by mutect2, pindel, varscan2
- MIS18BP1 | c.2068del p.S690Vfs*10 | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | catalogued as rs750307488; called by mutect2, varscan2
- MKLN1 | c.500G>T p.W167L | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.219); catalogued as COSV100759872; called by muse, mutect2, varscan2
- MKS1 | c.418-1G>A p.X140_splice | Splice Site (SNP) | VAF 10/34 reads (29%) | catalogued as COSV100439660; called by muse, mutect2, varscan2
- MMP17 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1009412157, COSV100861947; called by muse, mutect2, varscan2
- MOCS1 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs200517455, COSV57934931; called by muse, varscan2
- MRC2 | c.3119C>T p.A1040V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.268); catalogued as COSV100316344; called by muse, mutect2, varscan2
- MROH2B | c.3335C>T p.A1112V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.058); catalogued as rs1316385088, COSV101270734; called by muse, mutect2, varscan2
- MST1R | c.1663C>T p.Q555* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as COSV56572624; called by muse, mutect2
- MSX1 | c.485del p.P162Qfs*55 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | catalogued as rs762477502; called by mutect2, pindel, varscan2
- MTFMT | c.688G>T p.G230* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV99584385; called by muse, mutect2, varscan2
- MTG1 | c.766T>C p.Y256H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs375188629; called by muse, mutect2, varscan2
- MTMR7 | c.1588C>T p.Q530* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99472501; called by muse, mutect2, varscan2
- MUC17 | c.11026C>T p.P3676S | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV60298628; called by muse, mutect2, varscan2
- MUC4 | c.15857G>A p.R5286H (on ENST00000463781 / NM_018406.7; = p.R1050H on NM_004532.6) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs973002287, COSV57779073; called by muse, mutect2, varscan2
- MUC5AC | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); catalogued as COSV100650620; called by muse, mutect2, varscan2
- MX1 | c.900G>T p.K300N | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.288); catalogued as rs969213305, COSV99912704; called by muse, mutect2, varscan2
- MXRA5 | c.2387C>A p.P796H | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV99477433; called by muse, mutect2, varscan2
- MYH1 | c.1461A>T p.K487N | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99876179; called by muse, mutect2, varscan2
- MYH11 | c.4159G>A p.V1387M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as rs773946923, COSV100259299; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH8 | c.1204C>A p.L402I | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.146); catalogued as COSV101238464; called by muse, mutect2
- MYO9B | c.587A>G p.N196S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1422511100, COSV101261629; called by muse, mutect2, varscan2
- MYT1 | c.2297C>T p.S766L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.105); catalogued as rs747169479, COSV60511009; called by muse, mutect2, varscan2
- NADSYN1 | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs200388624, COSV59812601, COSV99074209; called by muse, mutect2, varscan2
- NANS | c.134A>T p.E45V | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV99271272; called by muse, mutect2
- NAT8 | c.137T>C p.L46S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs781092134, COSV99722038; called by muse, mutect2, varscan2
- NBEAL1 | c.4896C>G p.I1632M | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV101495725; called by muse, mutect2, varscan2
- NDST2 | c.1930T>C p.F644L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV100014064; called by muse, mutect2, varscan2
- NES | c.3224del p.G1075Vfs*40 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | catalogued as rs1483737122; called by mutect2, pindel
- NIPAL3 | c.44C>A p.P15H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.299); catalogued as COSV99135294; called by muse, mutect2, varscan2
- NISCH | c.3870G>T p.K1290N | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV100401854; called by muse, mutect2
- NKAIN1 | c.418C>T p.L140F | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772712756, COSV99744560; called by muse, mutect2, varscan2
- NKD1 | c.862dup p.R288Pfs*12 | Frame Shift Ins (INS) | VAF 7/29 reads (24%) | catalogued as rs772439983; called by mutect2, varscan2
- NKG7 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as rs760395622, COSV52467468; called by muse, mutect2, varscan2
- NLRC3 | c.3108T>C p.N1036= | Splice Region (SNP) | VAF 16/45 reads (36%) | catalogued as COSV100072923; called by muse, mutect2, varscan2
- NLRP2 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as rs1428884992, COSV99672355; called by muse, mutect2, varscan2
- NLRP4 | c.2941A>G p.T981A | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100016485; called by muse, mutect2, varscan2
- NOL4L | c.396del p.Y133Tfs*20 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs751187638; called by mutect2, varscan2
- NOP2 | c.1382C>T p.A461V (on ENST00000322166 / NM_001258308.2; = p.A457V on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100351203; called by muse, mutect2, varscan2
- NOS2 | c.2665C>A p.L889M | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV100569710; called by muse, mutect2, varscan2
- NOTCH1 | c.6109G>A p.A2037T | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53045977, COSV53099096; called by muse, varscan2
- NOTCH3 | c.4841T>C p.L1614S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.771); catalogued as COSV99657598; called by muse, varscan2
- NPAP1 | c.2947A>G p.R983G | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100275547; called by muse, mutect2, varscan2
- NR1D1 | c.1498C>A p.R500S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV52844745, COSV99225563; called by muse, mutect2, varscan2
- NRP1 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs777048356, COSV55161126; called by muse, mutect2, varscan2
- NRXN2 | c.3685C>T p.R1229C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55447324; called by muse, mutect2, varscan2
- NUAK2 | c.1324del p.L442Cfs*38 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as rs753375361; called by mutect2, varscan2
- NUP42 | c.212dup p.S72Qfs*13 | Frame Shift Ins (INS) | VAF 8/34 reads (24%) | catalogued as rs758695627; called by mutect2, varscan2
- NUP43 | c.1025T>C p.I342T | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV61189209; called by muse, mutect2
- NWD1 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs148848880; called by muse, varscan2
- NYAP2 | c.872G>A p.S291N | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.1); catalogued as COSV99797070; called by muse, mutect2, varscan2
- OAS3 | c.2071C>A p.L691I | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as COSV99966345; called by muse, mutect2, varscan2
- ODF3L1 | c.797G>A p.C266Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.694); catalogued as rs773224138, COSV100150779; called by muse, varscan2
- OPHN1 | c.376T>G p.F126V | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100830539; called by muse, mutect2
- OR10Q1 | c.648C>A p.F216L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as COSV100372192, COSV100372319; called by muse, mutect2
- OR13H1 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV100088299; called by muse, mutect2, varscan2
- OR2B6 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.246); catalogued as COSV99773790; called by muse, mutect2
- OR51B6 | c.706C>T p.L236F | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.533); catalogued as rs1489083040, COSV100971439, COSV66513837; called by muse, mutect2, varscan2
- OR52H1 | c.201G>A p.M67I (on ENST00000322653; = p.M73I on NM_001005289.1) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV100497336; called by muse, mutect2, varscan2
- OR52N4 | c.609G>A p.M203I | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as rs1246120428, COSV100421693; called by muse, mutect2, varscan2
- OR6B2 | c.875T>C p.L292P | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99401509; called by muse, mutect2, varscan2
- OR6V1 | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101389406; called by muse, mutect2, varscan2
- OR8H3 | c.724G>A p.V242I | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs186768016, COSV57907283; called by muse, mutect2, varscan2
- ORC6 | c.507del p.A170Lfs*10 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as rs35441257; called by mutect2, pindel, varscan2
- OSBPL3 | c.770C>A p.A257D | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.623); catalogued as COSV100514229; called by muse, mutect2, varscan2
- OSBPL5 | c.2219G>A p.R740H | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs374070869; called by muse, mutect2, varscan2
- OSGEPL1 | c.773A>G p.H258R | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV99918403; called by muse, mutect2, varscan2
- OSTC | c.50T>C p.L17P | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV100843207; called by muse, mutect2, varscan2
- OTUB2 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV99180184; called by muse, mutect2, varscan2
- PADI2 | c.441G>T p.Q147H | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV64945383; called by muse, mutect2, varscan2
- PAK1 | c.1315A>G p.K439E | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV99583569; called by muse, mutect2, varscan2
- PANX3 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs763115347, COSV99421560; called by muse, mutect2, varscan2
- PCDH10 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1332372413, COSV52087391; called by muse, mutect2, varscan2
- PCDHA10 | c.1193C>A p.S398Y | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100248584; called by muse, mutect2, varscan2
- PCDHGA4 | c.962A>G p.Q321R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.824); catalogued as COSV99540145; called by muse, mutect2, varscan2
- PCDHGA5 | c.2315A>G p.Q772R | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.38); catalogued as COSV99540149; called by muse, mutect2, varscan2
- PCDHGB6 | c.1513G>A p.V505M | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54004033, COSV99540152; called by muse, mutect2, varscan2
- PCID2 | c.657G>T p.K219N | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV99872509; called by muse, mutect2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as COSV61618667; called by mutect2, varscan2
- PCNT | c.3518T>C p.L1173P | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100855630; called by muse, mutect2, varscan2
- PDE9A | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0.131); catalogued as rs370673669, COSV99371693; called by muse, varscan2
- PDGFRA | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV99956810; called by muse, mutect2, varscan2
- PDLIM1 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.647); catalogued as rs565368926; called by muse, mutect2, varscan2
- PFKM | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1022005929, COSV56660361; called by muse, mutect2, varscan2
- PGAM4 | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.083); catalogued as COSV100431023; called by muse, mutect2, varscan2
- PHACTR2 | c.983_984insA p.V329Cfs*15 | Frame Shift Ins (INS) | VAF 8/42 reads (19%) | catalogued as COSV99991819; called by mutect2, pindel, varscan2
- PHC3 | c.1649C>T p.A550V (on ENST00000494943 / NM_001308116.2; = p.A562V on NM_024947.4) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.956); catalogued as rs1430598552, COSV101520171; called by muse, mutect2
- PIK3CA | c.2050T>C p.F684L | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV99838794; called by muse, mutect2, varscan2
- PITPNB | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV58060951; called by muse, mutect2, varscan2
- PKDREJ | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.059); catalogued as COSV99479031; called by muse, mutect2
- PKHD1L1 | c.2320A>G p.T774A | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV101006305; called by muse, mutect2, varscan2
- PLCE1 | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV99595301; called by muse, mutect2, varscan2
- PLD4 | c.611C>A p.P204H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV101190514; called by muse, mutect2, varscan2
- PLEC | c.11348G>T p.R3783L (on ENST00000322810 / NM_201380.4; = p.R3673L on NM_000445.5) | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as rs562181035, COSV59626135; called by muse, mutect2
- PLEKHH1 | c.2953A>G p.I985V | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as COSV100233225; called by muse, mutect2, varscan2
- PLEKHH1 | c.3595A>G p.K1199E | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV100233226; called by muse, mutect2, varscan2
- PLRG1 | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.796); catalogued as rs770806384, COSV100123140; called by muse, mutect2, varscan2
- PLXNA1 | c.356T>G p.L119R | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99303310; called by muse, mutect2, varscan2
- PLXNA3 | c.3658G>T p.A1220S | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100860029; called by muse, mutect2
- PNCK | c.923G>A p.R308H (on ENST00000340888 / NM_001366975.1; = p.R391H on NM_001039582.3) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs782198402, COSV100562354; called by muse, mutect2, varscan2
- POLDIP2 | c.545T>C p.L182P | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99134804; called by muse, mutect2, varscan2
- POLQ | c.2039T>C p.M680T | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as rs111660669, COSV99952386; called by muse, mutect2, varscan2
- POP1 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1296636880, COSV100855912; called by muse, mutect2, varscan2
- POT1 | c.668A>G p.Y223C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62929665; called by muse, mutect2, varscan2
- POU2F2 | c.1078G>A p.A360T (on ENST00000526816 / NM_001207025.3; = p.A344T on NM_002698.5) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.294); catalogued as COSV100657384; called by muse, mutect2, varscan2
- PRAMEF17 | c.922C>A p.Q308K | Missense Mutation (SNP) | VAF 67/262 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV101068743; called by muse, mutect2, varscan2
- PRKDC | c.496del p.I166Yfs*6 | Frame Shift Del (DEL) | VAF 36/62 reads (58%) | catalogued as rs537061158; called by mutect2, varscan2
- PRPF18 | c.249+1G>A p.X83_splice | Splice Site (SNP) | VAF 12/41 reads (29%) | catalogued as COSV100187143; called by muse, mutect2, varscan2
- PRPF19 | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV57127849; called by muse, mutect2, varscan2
- PRPS1L1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.646); catalogued as rs751865681, COSV72649817; called by muse, mutect2, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 32/66 reads (48%) | catalogued as rs781858060; called by mutect2, varscan2
- PRSS53 | c.172G>T p.G58* | Nonsense Mutation (SNP) | VAF 5/72 reads (7%) | catalogued as COSV99762409; called by muse, mutect2
- PSMD1 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1041647654; called by muse, mutect2, varscan2
- PTPN13 | c.855del p.K285Nfs*45 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs754278242; called by mutect2, varscan2
- PVRIG | c.236del p.G79Afs*245 | Frame Shift Del (DEL) | VAF 31/106 reads (29%) | catalogued as rs768997455; called by mutect2, pindel, varscan2
- QSER1 | c.5090del p.N1697Mfs*4 (on ENST00000399302; = p.N1826Mfs*4 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 22/85 reads (26%) | catalogued as rs754588466; called by mutect2, varscan2
- R3HDM1 | c.734A>G p.D245G | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV99926347; called by mutect2, varscan2
- RAB3C | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1230497313, COSV51437659; called by muse, mutect2
- RABEPK | c.239G>A p.C80Y | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV99413486; called by muse, mutect2
- RAD51 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV99139274; called by mutect2, varscan2
- RAD51AP2 | c.2410G>A p.E804K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as COSV101208358; called by muse, mutect2, varscan2
- RARA | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54189619, COSV99564798; called by muse, mutect2, varscan2
- RASGRP2 | c.1479del p.R494Afs*25 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | catalogued as rs774996406; called by mutect2, pindel, varscan2
- RAVER2 | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99605320; called by muse, mutect2, varscan2
- RBM14 | c.1877G>A p.R626H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.744); catalogued as rs577465036, COSV59561479; called by muse, mutect2, varscan2
- RBM19 | c.1631C>T p.T544I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99926229; called by muse, mutect2, varscan2
- RBM42 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1256810879, COSV99387064; called by muse, mutect2, varscan2
- RHBG | c.983T>C p.I328T | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs748520513, COSV99659681; called by muse, mutect2, varscan2
- RNF128 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 18/95 reads (19%) | catalogued as COSV99718261; called by muse, mutect2, varscan2
- RNF17 | c.2761C>T p.H921Y | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV99693470; called by muse, mutect2, varscan2
- RNF26 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs977360015, COSV100264841; called by muse, mutect2, varscan2
- RNPS1 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs374469152; called by muse, mutect2
- RP1L1 | c.2012G>A p.R671H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs747521627, COSV66753400; called by muse, mutect2, varscan2
- RP1L1 | c.851del p.P284Rfs*26 | Frame Shift Del (DEL) | VAF 27/100 reads (27%) | catalogued as rs757272743; called by mutect2, pindel, varscan2
- RPL17-C18orf32 | c.145A>G p.K49E | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.401); catalogued as COSV100271707; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6KA5 | c.1828G>A p.V610I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.93); catalogued as rs759541597, COSV56221937; called by muse, mutect2
- RPS6KA5 | c.1472A>G p.Q491R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs1379356994, COSV100002718; called by muse, varscan2
- RPS6KB1 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.952); catalogued as COSV99847565; called by muse, mutect2, varscan2
- RRP12 | c.2989C>T p.R997W | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773783036, COSV100213253; called by muse, mutect2, varscan2
- RSPH10B | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 37/129 reads (29%) | catalogued as COSV100521328; called by muse, mutect2, varscan2
- RSPH6A | c.478G>T p.G160C | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.258); catalogued as COSV55573595, COSV99679865; called by muse, mutect2, varscan2
- RSRC2 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.519); catalogued as rs367924996; called by muse, mutect2, varscan2
- RTN4 | c.3013+2T>C p.X1005_splice | Splice Site (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100463342; called by muse, mutect2, varscan2
- RUNX1T1 | c.725G>T p.R242M (on ENST00000265814 / NM_001198628.1; = p.R215M on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99752666; called by muse, mutect2, varscan2
- SCN4A | c.2266C>T p.R756C | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771740205, COSV71128612, COSV71129081; called by muse, mutect2, varscan2
- SCN8A | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.867); catalogued as COSV100633951; called by muse, mutect2, varscan2
- SECISBP2L | c.1413del p.K471Nfs*20 (on ENST00000559471 / NM_001193489.2; = p.K426Nfs*20 on NM_014701.4) | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs768725524; called by mutect2, varscan2
- SEMA5B | c.1310T>C p.L437P | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99532180; called by muse, mutect2, varscan2
- SENP7 | c.94A>G p.R32G | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV100053374; called by muse, mutect2, varscan2
- SESTD1 | c.485T>G p.V162G | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as COSV100090587; called by muse, mutect2
- SGIP1 | c.1901A>G p.D634G | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99391818; called by muse, mutect2, varscan2
- SH3GL3 | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV100196916; called by muse, mutect2, varscan2
- SH3PXD2A | c.3100G>A p.E1034K (on ENST00000369774 / NM_001365079.1; = p.E1006K on NM_014631.2) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as rs371597796; called by muse, mutect2
- SH3RF2 | c.650A>G p.D217G | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.339); catalogued as COSV100767819; called by muse, mutect2, varscan2
- SHROOM4 | c.3800del p.P1267Qfs*21 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as COSV99175097; called by mutect2, pindel, varscan2
- SI | c.4814G>A p.G1605D | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.101); catalogued as COSV100015903; called by muse, mutect2, varscan2
- SIGLEC1 | c.496T>C p.C166R | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1043613759, COSV99166738; called by muse, mutect2, varscan2
- SLAMF1 | c.829del p.S277Afs*54 | Frame Shift Del (DEL) | VAF 23/110 reads (21%) | catalogued as rs751442558; called by mutect2, varscan2
- SLAMF1 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.165); catalogued as COSV52499923; called by muse, mutect2, varscan2
- SLC22A18 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770154192, COSV100388840; called by muse, mutect2, varscan2
- SLC34A2 | c.1925G>T p.S642I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as COSV101158380; called by muse, mutect2, varscan2
- SLC36A1 | c.513A>C p.E171D | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as COSV99695606; called by muse, mutect2, varscan2
- SLC39A5 | c.934G>T p.G312W | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99907545; called by muse, mutect2
- SLC3A2 | c.544C>A p.R182S | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100101434; called by muse, mutect2, varscan2
- SLC44A4 | c.242+2T>C p.X81_splice | Splice Site (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99999024; called by muse, mutect2, varscan2
- SLC45A2 | c.869dup p.N290Kfs*6 | Frame Shift Ins (INS) | VAF 4/14 reads (29%) | catalogued as rs1195350614; called by mutect2, varscan2
- SLC4A10 | c.1294T>C p.W432R (on ENST00000446997 / NM_001354461.2; = p.W402R on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99764534; called by muse, varscan2
- SLC52A3 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99448030; called by muse, mutect2, varscan2
- SMARCA2 | c.4399C>A p.L1467M | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV100190536; called by muse, mutect2, varscan2
- SMG1 | c.3490A>C p.N1164H | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.69); catalogued as COSV101246196; called by muse, mutect2, varscan2
- SNAPC4 | c.2851C>T p.P951S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as rs1162467259, COSV100047351; called by mutect2, varscan2
- SORBS3 | c.219G>T p.P73= | Splice Region (SNP) | VAF 9/50 reads (18%) | catalogued as COSV99531327; called by muse, mutect2, varscan2
- SORCS1 | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV99547418; called by muse, mutect2, varscan2
- SORCS3 | c.3613G>A p.A1205T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.05); catalogued as rs1263391406, COSV100865262; called by muse, mutect2, varscan2
- SP140 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.118); catalogued as COSV59457613; called by muse, mutect2, varscan2
- SPATA17 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 9/60 reads (15%) | catalogued as COSV100861187; called by muse, mutect2, varscan2
- SPATS2L | c.332G>A p.C111Y | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100660757; called by muse, mutect2, varscan2
- SPEG | c.8475del p.T2826Hfs*78 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | catalogued as rs1219842225, COSV56662195; called by mutect2, pindel, varscan2
- SPHKAP | c.3685C>T p.R1229* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as rs1359828809, COSV100764212; called by muse, mutect2, varscan2
- SPTY2D1 | c.499A>T p.M167L | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100311721; called by muse, mutect2, varscan2
- SRSF2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV100333985, COSV57975466; called by muse, mutect2, varscan2
- SRSF3 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.964); catalogued as rs760340535, COSV59672375; called by muse, mutect2, varscan2
- SSH1 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1222844460, COSV58457131; called by mutect2, varscan2
- STAT6 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1415463289, COSV100273373; called by muse, mutect2, varscan2
- STOML2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100521355; called by muse, mutect2, varscan2
- STRA8 | c.464_467del p.K155Rfs*6 (on ENST00000275764; = p.K133Rfs*6 on NM_182489.2) | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | catalogued as rs763215346; called by mutect2, pindel, varscan2
- STX18 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as rs754364875, COSV100086215; called by muse, mutect2
- SUGP1 | c.1924C>T p.R642W | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV55920607; called by muse, mutect2, varscan2
- SUV39H2 | c.296A>T p.N99I (on ENST00000354919 / NM_001193424.2; = p.N39I on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV100543118, COSV57954215; called by muse, mutect2, varscan2
- SYDE1 | c.1999C>T p.R667W | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1371727331, COSV54617791; called by muse, mutect2, varscan2
- SYNCRIP | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.586); catalogued as COSV62287603; called by muse, mutect2, varscan2
- SYNE2 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.644); catalogued as rs374073818; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYT5 | c.655C>A p.L219M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV62831197; called by muse, mutect2, varscan2
- TAF5L | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.142); catalogued as COSV99273287; called by muse, mutect2, varscan2
- TBC1D21 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.988); catalogued as rs754397398, COSV100311383; called by muse, mutect2, varscan2
- TCEA2 | c.518G>A p.C173Y | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1003112123, COSV100180771; called by muse, mutect2, varscan2
- TCTA | c.164T>G p.L55R | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99648653; called by muse, mutect2, varscan2
- TENM1 | c.7593G>T p.K2531N | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.175); catalogued as COSV100950278; called by muse, mutect2, varscan2
- TEX11 | c.1309C>A p.L437I (on ENST00000344304; = p.L422I on NM_031276.3) | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV100721856; called by muse, mutect2
- TEX14 | c.1016A>G p.H339R (on ENST00000240361 / NM_001201457.2; = p.H333R on NM_031272.5) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99542501; called by muse, mutect2, varscan2
- TEX44 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as rs143893162, COSV100009780; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2045C>T p.A682V | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780247252, COSV99305193; called by muse, mutect2, varscan2
- THBS1 | c.956A>G p.Y319C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV99528026; called by muse, mutect2, varscan2
- THOC3 | c.419C>T p.T140I | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV99442142; called by muse, mutect2, varscan2
- THRAP3 | c.2153G>A p.R718H | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1330733410, COSV63568698, COSV63570182; called by muse, mutect2, varscan2
- TKFC | c.1112C>A p.S371* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as COSV99582497; called by muse, mutect2, varscan2
- TMCO3 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs1015421846, COSV64807595; called by muse, mutect2, varscan2
- TMCO3 | c.1879C>A p.L627M | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100952350; called by muse, mutect2
- TMEM150C | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV101496928; called by muse, mutect2
- TMEM156 | c.98T>C p.L33S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV100756060; called by muse, mutect2
- TMPRSS9 | c.793G>A p.A265T (on ENST00000648592; = p.A231T on NM_182973.2) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs371030548; called by muse, mutect2, varscan2
- TNC | c.1046C>A p.A349D | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100405908; called by muse, varscan2
- TNFRSF19 | c.449C>A p.A150D | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV99947464; called by muse, mutect2, varscan2
- TNK1 | c.1543G>T p.G515W (on ENST00000576812 / NM_001251902.2; = p.G510W on NM_003985.5) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV100247945; called by muse, mutect2, varscan2
- TNKS | c.3697G>T p.G1233C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100127235; called by muse, mutect2, varscan2
- TNRC18 | c.4648C>T p.H1550Y | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV101269702; called by muse, mutect2, varscan2
- TOPBP1 | c.1160T>C p.V387A | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV99605428; called by muse, mutect2, varscan2
- TRAF1 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as rs34536586, COSV100875160; called by muse, mutect2, varscan2
- TRANK1 | c.7001G>A p.S2334N | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100083360; called by muse, mutect2, varscan2
- TSPAN31 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs763198055, COSV57276750, COSV99226038; called by muse, mutect2, varscan2
- TSR2 | c.143del p.G48Vfs*15 | Frame Shift Del (DEL) | VAF 18/112 reads (16%) | catalogued as rs1266253882, COSV64309766; called by mutect2, pindel, varscan2
- TTC12 | c.754C>A p.L252I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100133156; called by muse, mutect2, varscan2
- TTC22 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100988163; called by muse, mutect2, varscan2
- TUT4 | c.3127G>T p.G1043C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99932470; called by muse, mutect2, varscan2
- TUT7 | c.1612T>C p.S538P | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99463169; called by muse, mutect2, varscan2
- UBXN6 | c.301G>T p.G101W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV100011864; called by mutect2, varscan2
- UMODL1 | c.2742T>A p.C914* (on ENST00000408910 / NM_001004416.2; = p.C1042* on NM_173568.3) | Nonsense Mutation (SNP) | VAF 5/54 reads (9%) | catalogued as COSV101252604; called by muse, mutect2
- UNC5D | c.2281C>A p.L761I | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99776082; called by muse, mutect2, varscan2
- USP35 | c.1962del p.T655Pfs*23 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as rs764735138; called by mutect2, varscan2
- USP54 | c.2309G>A p.G770E | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100357431; called by muse, mutect2, varscan2
- USP7 | c.959T>C p.I320T | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100784220; called by muse, mutect2
- VCAM1 | c.1292A>G p.Y431C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99658634; called by muse, mutect2, varscan2
- VIP | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs765672950, COSV100923940; called by muse, mutect2, varscan2
- VIRMA | c.599C>A p.P200H | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV99888608; called by muse, mutect2
- VPS13B | c.16G>A p.V6I | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.994); catalogued as rs1356466453, COSV100662323; called by muse, mutect2, varscan2
- VPS39 | c.455G>T p.R152M (on ENST00000348544 / NM_001301138.2; = p.R141M on NM_015289.5) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV100529288; called by muse, mutect2, varscan2
- VSIG2 | c.297del p.T100Qfs*7 | Frame Shift Del (DEL) | VAF 19/78 reads (24%) | catalogued as rs766405238; called by mutect2, pindel, varscan2
- WARS2 | c.735G>T p.E245D | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.87); PolyPhen benign (0.023); catalogued as COSV99346450; called by muse, mutect2
- WASL | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.831); catalogued as COSV99771703; called by muse, mutect2, varscan2
- WDR89 | c.746T>C p.L249P | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as COSV99962464; called by muse, mutect2, varscan2
- WNK2 | c.4001C>A p.P1334H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99942990; called by muse, mutect2, varscan2
- XIRP2 | c.1537del p.D513Mfs*5 (on ENST00000628543; = p.D688Mfs*5 on NM_152381.6) | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | catalogued as rs745648385; called by mutect2, varscan2
- XPO7 | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.726); catalogued as rs1486570253, COSV53010896; called by muse, mutect2, varscan2
- YTHDC1 | c.2020C>T p.R674W (on ENST00000344157 / NM_001031732.4; = p.R656W on NM_133370.4) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs756562328, COSV60009675; called by muse, mutect2
- YTHDC2 | c.1361C>G p.T454S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV99363476; called by muse, mutect2, varscan2
- ZBTB26 | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101021103; called by mutect2, varscan2
- ZBTB34 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.375); catalogued as rs1310802650, COSV59860678; called by muse, mutect2, varscan2
- ZC3H18 | c.1739G>T p.S580I | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99964182; called by muse, mutect2, varscan2
- ZMIZ1 | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100565785, COSV57889858; called by muse, mutect2, varscan2
- ZMIZ1 | c.3037G>A p.A1013T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.08); catalogued as rs1470915263, COSV100565881; called by muse, mutect2, varscan2
- ZMYM3 | c.480G>T p.E160D | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.001); catalogued as COSV100078008; called by muse, mutect2
- ZMYND8 | c.1025C>T p.A342V (on ENST00000311275 / NM_001363741.2; = p.A362V on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99520699; called by muse, mutect2
- ZNF148 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs772853339, COSV100642123; called by muse, mutect2, varscan2
- ZNF217 | c.2768G>A p.S923N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100184523; called by muse, mutect2, varscan2
- ZNF35 | c.163G>T p.G55C | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as COSV99940078; called by muse, mutect2, varscan2
- ZNF396 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100108579; called by muse, mutect2, varscan2
- ZNF41 | c.869A>G p.Q290R | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.087); catalogued as rs748114203, COSV100492120; called by muse, mutect2, varscan2
- ZNF415 | c.1421G>C p.G474A | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV99701666, COSV99702196; called by muse, mutect2, varscan2
- ZNF496 | c.1477C>T p.P493S | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV54180305; called by muse, mutect2, varscan2
- ZNF507 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.106); catalogued as rs755497497, COSV100321893; called by muse, mutect2, varscan2
- ZNF514 | c.398A>G p.H133R | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV99727787; called by muse, mutect2
- ZNF518A | c.3961A>C p.K1321Q | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100283576; called by muse, mutect2
- ZNF687 | c.65A>T p.D22V | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100133829, COSV100134303; called by muse, mutect2, varscan2
- ZNF699 | c.338G>A p.C113Y | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100426974; called by muse, mutect2, varscan2
- ZNF7 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs371582136, COSV100295920; called by muse, mutect2, varscan2
- ZP3 | c.1108A>G p.R370G (on ENST00000394857 / NM_001110354.2; = p.R319G on NM_007155.6) | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100334565; called by muse, mutect2, varscan2
- AFDN | c.3041del p.K1014Sfs*20 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- ARID1A | c.3216del p.K1072Nfs*21 | Frame Shift Del (DEL) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- ATP2C2 | c.778del p.X260_splice | Splice Site (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- ATXN1 | c.449del p.P150Qfs*38 | Frame Shift Del (DEL) | VAF 19/79 reads (24%) | called by mutect2, pindel, varscan2
- AXIN1 | c.2503del p.V835Wfs*103 | Frame Shift Del (DEL) | VAF 22/61 reads (36%) | called by mutect2, pindel, varscan2
- BAG6 | c.344del p.P115Lfs*53 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- BICRAL | c.2689del p.T897Qfs*8 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by pindel, varscan2
- BRINP3 | c.1866dup p.E623* | Frame Shift Ins (INS) | VAF 14/73 reads (19%) | called by mutect2, pindel, varscan2
- BSX | c.673del p.E225Sfs*17 | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | called by mutect2, pindel, varscan2
- C3orf56 | c.375del p.N126Tfs*7 | Frame Shift Del (DEL) | VAF 25/92 reads (27%) | called by mutect2, pindel, varscan2
- C9orf131 | c.883_885del p.H295del | In Frame Del (DEL) | VAF 10/42 reads (24%) | called by mutect2, pindel, varscan2
- CHD7 | c.3059del p.L1020* | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | called by mutect2, pindel, varscan2
- CHPF | c.925del p.E309Sfs*14 | Frame Shift Del (DEL) | VAF 8/94 reads (9%) | called by mutect2, pindel
- CIART | c.639del p.P214Qfs*24 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- CNGA4 | c.531del p.F177Lfs*51 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | called by mutect2, pindel, varscan2
- DCAF11 | c.1298del p.G433Afs*39 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, pindel, varscan2
- DIDO1 | c.6101dup p.Q2035Afs*58 | Frame Shift Ins (INS) | VAF 5/32 reads (16%) | called by mutect2, pindel, varscan2
- DROSHA | c.470del p.P157Lfs*69 | Frame Shift Del (DEL) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- DSG3 | c.1187dup p.S397Kfs*2 | Frame Shift Ins (INS) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- FAM187B | c.754del p.L252* | Frame Shift Del (DEL) | VAF 12/79 reads (15%) | called by mutect2, pindel, varscan2
- FBN1 | c.2410del p.T804Hfs*43 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- FOSL1 | c.585del p.C196Afs*26 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | called by mutect2, pindel, varscan2
- FXR1 | c.568_578del p.R190Yfs*10 | Frame Shift Del (DEL) | VAF 16/101 reads (16%) | called by mutect2, pindel, varscan2
- GANAB | c.68del p.L23* | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | called by mutect2, pindel, varscan2
- GNL3 | c.71del p.K24Rfs*9 | Frame Shift Del (DEL) | VAF 16/77 reads (21%) | called by mutect2, pindel, varscan2
- GPR160 | c.715del p.I239Yfs*22 | Frame Shift Del (DEL) | VAF 13/104 reads (13%) | called by mutect2, pindel, varscan2
- GPR179 | c.127A>G p.K43E | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GTF2IRD2B | c.1473del p.L493Sfs*6 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, varscan2
- HSPB8 | c.147dup p.D50Rfs*77 | Frame Shift Ins (INS) | VAF 11/59 reads (19%) | called by mutect2, pindel, varscan2
- IGHV5-51 | c.190C>A p.L64M | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- KCNJ10 | c.305C>A p.P102Q | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.912); called by muse, mutect2
- KIF9 | c.659del p.F220Sfs*5 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | called by mutect2, pindel, varscan2
- KLF3 | c.318del p.K106Nfs*21 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | called by mutect2, pindel, varscan2
- KLHL31 | c.557del p.N186Mfs*24 | Frame Shift Del (DEL) | VAF 21/59 reads (36%) | called by mutect2, pindel, varscan2
- KMT2C | c.4802del p.N1601Ifs*64 | Frame Shift Del (DEL) | VAF 21/101 reads (21%) | called by mutect2, pindel, varscan2
- LAMA5 | c.6404dup p.L2137Afs*29 | Frame Shift Ins (INS) | VAF 18/82 reads (22%) | called by mutect2, pindel, varscan2
- MCOLN1 | c.605del p.P202Lfs*36 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | called by mutect2, pindel, varscan2
- MRTFA | c.2695del p.Q899Rfs*29 | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | called by mutect2, pindel, varscan2
- MTUS2 | c.2871_2872del p.R957Sfs*35 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by pindel, varscan2
- NAB2 | c.632del p.P211Lfs*58 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- NLRC5 | c.5437del p.A1813Pfs*32 | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | called by mutect2, pindel, varscan2
- NLRP9 | c.791del p.K264Rfs*12 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | called by mutect2, pindel, varscan2
- NPC1 | c.2279_2281del p.F760del | In Frame Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, varscan2
- PAX2 | c.1207del p.R403Gfs*37 (on ENST00000428433 / NM_003987.5; = p.R380Gfs*37 on NM_000278.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- PGBD1 | c.565dup p.H189Pfs*21 | Frame Shift Ins (INS) | VAF 22/87 reads (25%) | called by mutect2, pindel, varscan2
- PNPLA6 | c.210_212del p.V71del (on ENST00000414982 / NM_001166111.2; = p.V23del on NM_006702.5) | In Frame Del (DEL) | VAF 11/45 reads (24%) | called by pindel, varscan2
- POC1B | c.186_188del p.V63del | In Frame Del (DEL) | VAF 12/48 reads (25%) | called by pindel, varscan2
- POLR3B | c.634del p.S212Afs*7 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | called by mutect2, pindel, varscan2
- PRDM11 | c.1213del p.V405Sfs*47 (on ENST00000530656 / NM_001359633.1; = p.V371Sfs*47 on NM_001256695.1) | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- PRSS53 | c.1201del p.L401Sfs*36 | Frame Shift Del (DEL) | VAF 15/61 reads (25%) | called by mutect2, pindel, varscan2
- RABEP2 | c.842del p.P281Lfs*40 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel
- RBM15 | c.413del p.G138Afs*35 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, varscan2
- RIMBP3 | c.3636del p.V1213Sfs*31 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, varscan2
- RUSF1 | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2
- SLC49A4 | c.1268del p.L423* | Frame Shift Del (DEL) | VAF 11/63 reads (17%) | called by mutect2, pindel, varscan2
- SNAI1 | c.749del p.L250Rfs*30 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- SPOCK3 | c.1018dup p.L340Pfs*3 | Frame Shift Ins (INS) | VAF 6/45 reads (13%) | called by mutect2, pindel, varscan2
- TIAM2 | c.651del p.S218Pfs*26 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, varscan2
- TM4SF4 | c.60del p.F20Lfs*16 | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | called by mutect2, varscan2
- TTN | c.9059del p.K3020Sfs*6 (on ENST00000591111; = p.K2974Sfs*6 on NM_003319.4) | Frame Shift Del (DEL) | VAF 46/197 reads (23%) | called by mutect2, pindel, varscan2
- TULP3 | c.1190del p.N397Mfs*6 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | called by mutect2, pindel, varscan2
- ZC3H13 | c.4042_4043dup p.R1349Nfs*15 | Frame Shift Ins (INS) | VAF 30/120 reads (25%) | called by mutect2, varscan2
- ZFP36L2 | c.431del p.G144Afs*43 | Frame Shift Del (DEL) | VAF 19/66 reads (29%) | called by mutect2, pindel, varscan2
- ZGRF1 | c.454del p.S152Lfs*18 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | called by mutect2, pindel, varscan2
- ZNF142 | c.3316dup p.I1106Nfs*72 (on ENST00000411696 / NM_001379660.1; = p.I906Nfs*72 on NM_001105537.4 and 5 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 23/76 reads (30%) | called by mutect2, pindel, varscan2
- ZNF362 | c.564del p.K189Sfs*21 | Frame Shift Del (DEL) | VAF 24/85 reads (28%) | called by mutect2, pindel, varscan2
- ACE2 | c.1783C>T p.L595= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV99382879; called by muse, mutect2, varscan2
- ADAM22 | c.1203C>T p.C401= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as COSV99717264; called by muse, mutect2, varscan2
- ADAMTS1 | c.1803A>G p.K601= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV99536244; called by muse, mutect2
- ADAMTS9 | c.2136C>T p.G712= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV99899622; called by muse, mutect2, varscan2
- ADRA1D | c.1218C>T p.S406= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV101063045; called by muse, mutect2, varscan2
- AHNAK | c.390G>A p.K130= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs1461162714, COSV99947945; called by muse, mutect2, varscan2
- AHNAK2 | c.13293G>T p.V4431= | Silent (SNP) | VAF 6/118 reads (5%) | catalogued as COSV100317854; called by muse, mutect2
- AIMP2 | c.285G>A p.A95= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs746565414, COSV56149812; called by muse, mutect2, varscan2
- AKAP12 | c.1507C>T p.L503= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99483612; called by muse, mutect2, varscan2
- ALDH5A1 | c.1059T>C p.H353= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV100708823; called by muse, mutect2, varscan2
- ANGPTL3 | c.804A>G p.Q268= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV99224823; called by muse, mutect2, varscan2
- ARRDC2 | c.411G>A p.R137= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV99716802; called by muse, mutect2, varscan2
- ASPM | c.9105G>A p.L3035= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV54129561, COSV99660562; called by muse, mutect2
- ASTN1 | c.3235C>T p.L1079= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as rs1242007846, COSV62497489; called by muse, mutect2, varscan2
- ATP9B | c.1344G>T p.T448= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV100303710, COSV56947892; called by muse, mutect2, varscan2
- CACNA1I | c.4236C>A p.I1412= | Silent (SNP) | VAF 10/214 reads (5%) | catalogued as COSV60808932; called by muse, mutect2
- CARMIL3 | c.2596C>T p.L866= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100549655; called by muse, mutect2, varscan2
- CCDC22 | c.1611G>A p.A537= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs143702029, COSV100873184, COSV66050946; called by muse, mutect2, varscan2
- CCDC39 | c.2367G>A p.T789= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs201806641, COSV56489518, COSV99868671; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCN5 | c.174G>A p.R58= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs1455358961, COSV99509368; called by muse, mutect2, varscan2
- CD300E | c.510C>T p.S170= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs142561295; called by muse, mutect2, varscan2
- CDH1 | c.2628C>T p.Y876= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs778681919, COSV55732965; ClinVar: likely benign; called by muse, mutect2, varscan2
- CFAP206 | c.796C>T p.L266= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV99739705; called by muse, mutect2, varscan2
- CHRNA4 | c.1086C>T p.S362= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs74396179, COSV100937434; called by muse, mutect2, varscan2
- CHST12 | c.633C>T p.S211= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs146540649, COSV51678556; called by muse, mutect2, varscan2
- CMTM1 | c.90C>T p.I30= (on ENST00000457188 / NM_181269.3; = p.I147= on NM_052999.4) | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99862615; called by muse, mutect2, varscan2
- CNKSR1 | c.2079C>A p.P693= (on ENST00000374253 / NM_001297647.2; = p.P686= on NM_006314.3) | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100128430; called by muse, mutect2, varscan2
- CNTN3 | c.1326C>T p.S442= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV99724845; called by muse, mutect2, varscan2
- COL4A2 | c.1761C>T p.G587= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs1395667139, COSV100847380; called by muse, mutect2, varscan2
- CPNE8 | c.795T>C p.Y265= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV100504549; called by muse, mutect2, varscan2
- CSPG5 | c.1269C>T p.C423= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs1218913767, COSV53132487; called by muse, mutect2, varscan2
- CUL7 | c.87C>T p.R29= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs150526488, COSV54822121; called by muse, mutect2, varscan2
- DCLRE1B | c.822T>C p.S274= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs377419500, COSV100849804; called by muse, mutect2, varscan2
- DHX9 | c.2703C>T p.G901= | Silent (SNP) | VAF 7/118 reads (6%) | catalogued as COSV100841433; called by muse, mutect2
- DNAH1 | c.11889C>T p.F3963= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as rs547237615, COSV99964105; called by muse, mutect2, varscan2
- DPH6 | c.762G>A p.V254= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV99853646; called by muse, mutect2, varscan2
- DSCAML1 | c.3639G>A p.E1213= (on ENST00000321322; = p.E1153= on NM_020693.4) | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV100356246; called by muse, mutect2, varscan2
- DUSP7 | c.627C>T p.G209= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs773029104, COSV99623527; called by muse, mutect2, varscan2
- DYNC1H1 | c.10083C>T p.D3361= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs772665813, COSV64137424; ClinVar: likely benign; called by muse, mutect2, varscan2
- DYNC1H1 | c.10374C>A p.A3458= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100795032; called by muse, mutect2, varscan2
- E2F1 | c.306C>T p.A102= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs1340141397, COSV100594014; called by muse, mutect2
- EMILIN1 | c.1020C>T p.L340= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs1479856722, COSV99566288; called by mutect2, varscan2
- EPPK1 | c.6621G>A p.T2207= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs781802244, COSV101599873; called by muse, mutect2, varscan2
- ERBB3 | c.867C>T p.S289= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV99917123; called by muse, mutect2, varscan2
- ERVW-1 | c.384T>C p.H128= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs916216768, COSV101423846; called by muse, mutect2, varscan2
- EXOSC4 | c.525T>C p.H175= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV100284093; called by muse, mutect2, varscan2
- EZHIP | c.576G>A p.S192= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV100539766; called by muse, mutect2, varscan2
- FAM199X | c.1023G>A p.Q341= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV100245551; called by muse, mutect2, varscan2
- FLT4 | c.1047C>T p.D349= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs754585862, COSV56119555; called by muse, varscan2
- FRMD5 | c.1431A>G p.G477= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV101296601; called by muse, mutect2, varscan2
- FTHL17 | c.513C>T p.F171= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV63267340; called by muse, mutect2, varscan2
- GAS6 | c.1668C>T p.A556= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs979434166, COSV100581705; called by mutect2, varscan2
- GDF6 | c.273C>T p.R91= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV54622739; called by muse, mutect2
- GLIS1 | c.219C>A p.T73= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV100390222; called by muse, mutect2, varscan2
- GPR75 | c.699T>G p.A233= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100766153; called by muse, varscan2
- GREB1 | c.522T>C p.H174= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV99303080; called by muse, mutect2, varscan2
- GRXCR1 | c.60C>T p.I20= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as rs267600162, COSV67669835; called by muse, mutect2, varscan2
- GSDMB | c.150G>A p.R50= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as rs546795381, COSV100401549; called by muse, mutect2, varscan2
- GTF2A1 | c.189G>A p.E63= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs930141262, COSV99993453; called by muse, mutect2
- HBP1 | c.960G>A p.Q320= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as COSV99753352; called by muse, mutect2
- HCN1 | c.2124A>G p.V708= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV57525339; called by muse, mutect2, varscan2
- HGFAC | c.1032C>T p.D344= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as rs140857364; called by muse, mutect2, varscan2
- HSPB7 | c.384G>A p.L128= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV100317973; called by muse, mutect2, varscan2
- HSPG2 | c.3012C>A p.S1004= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV101020506, COSV65968824; called by muse, mutect2, varscan2
- HYDIN | c.300C>A p.P100= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV55485248, COSV99863569; called by muse, mutect2, varscan2
- IFNA16 | c.129A>G p.Q43= | Silent (SNP) | VAF 29/136 reads (21%) | catalogued as COSV101207071; called by muse, mutect2, varscan2
- IGSF10 | c.7050G>A p.Q2350= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99180788; called by muse, mutect2, varscan2
- IGSF3 | c.624C>T p.S208= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs148335027; called by muse, mutect2, varscan2
- INHA | c.354C>A p.S118= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV99216779; called by muse, mutect2, varscan2
- ITGAM | c.111C>T p.S37= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs777607162, COSV99791719; called by muse, varscan2
- ITPRID2 | c.411T>C p.N137= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV100238391; called by muse, mutect2, varscan2
- JAG1 | c.633C>A p.A211= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV99653059; called by muse, mutect2
- JARID2 | c.1998C>T p.G666= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs139580359; called by muse, mutect2, varscan2
- JMJD7 | c.786G>T p.T262= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV100583993; called by muse, mutect2, varscan2
- JPH1 | c.861C>T p.N287= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs1174048027, COSV100646643; called by muse, mutect2, varscan2
- KANK2 | c.1407C>T p.A469= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as rs375798638; called by muse, mutect2, varscan2
- KAT6B | c.5355C>T p.P1785= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs138711901; ClinVar: likely benign; called by muse, mutect2
- KATNIP | c.795C>T p.N265= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV99851333; called by muse, mutect2, varscan2
- KCNC1 | c.1230G>A p.T410= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs1295549018, COSV56395300; called by muse, mutect2, varscan2
- KIF7 | c.3807C>T p.V1269= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV99176638; called by muse, varscan2
- KRT34 | c.181C>A p.R61= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as COSV101222663, COSV67449953; called by muse, mutect2, varscan2
- LIMK1 | c.1260G>A p.T420= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs782319481, COSV60279754; called by muse, mutect2, varscan2
- LMAN2 | c.768C>T p.S256= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs762638868, COSV100288409; called by muse, varscan2
- LRRC66 | c.222T>C p.V74= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100602997; called by muse, mutect2
- LSS | c.2154C>T p.R718= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV100710945; called by muse, mutect2, varscan2
- MAP3K19 | c.2049G>A p.T683= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs772463656, COSV100208716; called by muse, mutect2, varscan2
- MCPH1 | c.1665G>A p.A555= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs772338945, COSV100765891; called by muse, mutect2, varscan2
- MDFI | c.651C>T p.D217= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV100025674; called by muse, mutect2, varscan2
- MEF2B | c.237C>T p.R79= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV99364770; called by muse, mutect2, varscan2
- MIA2 | c.1998C>A p.T666= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV99697740; called by muse, mutect2, varscan2
- MICAL3 | c.4044G>A p.G1348= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV101490901; called by muse, mutect2, varscan2
- MLLT10 | c.288T>C p.D96= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV100308281; called by muse, mutect2, varscan2
- MTUS2 | c.78T>C p.N26= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs765507378, COSV101462270; called by muse, mutect2, varscan2
- MUC5B | c.9006G>A p.T3002= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as rs746927262, COSV71594678; called by muse, mutect2, varscan2
- MYO7B | c.1008G>A p.S336= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs757758194, COSV101268240; called by muse, mutect2, varscan2
- MYO9A | c.537T>C p.V179= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV100613717; called by mutect2, varscan2
- NAPEPLD | c.540G>A p.A180= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs764807728, COSV100439889; called by muse, mutect2, varscan2
- NDUFB8 | c.219C>T p.G73= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as rs1243228211, COSV100144096; called by muse, mutect2
- NIPSNAP1 | c.234T>C p.N78= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs779325415, COSV99331178; called by muse, varscan2
- NLN | c.942C>T p.R314= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs746668070, COSV101114335; called by muse, varscan2
- NLRC5 | c.5355T>G p.A1785= | Silent (SNP) | VAF 8/130 reads (6%) | catalogued as COSV99347544; called by muse, mutect2
- NOTCH3 | c.963C>A p.A321= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV99657602; called by muse, mutect2, varscan2
- NTN1 | c.1113T>C p.C371= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV99433195; called by muse, mutect2
- OPN3 | c.426C>T p.R142= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs570915682, COSV100087499; called by muse, mutect2
- OR10A2 | c.828C>A p.I276= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100225067, COSV56298658; called by muse, mutect2, varscan2
- OR4L1 | c.30C>T p.T10= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as rs370799664, COSV59849271; called by muse, mutect2, varscan2
- OTX1 | c.384G>A p.T128= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV99246371; called by muse, mutect2, varscan2
- PASD1 | c.1890T>C p.C630= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100949416; called by muse, mutect2, varscan2
- PCDHB6 | c.1965G>A p.T655= | Silent (SNP) | VAF 8/121 reads (7%) | catalogued as rs782188858, COSV50712725, COSV99170208; called by muse, mutect2
- PCDHB6 | c.2160G>A p.V720= | Silent (SNP) | VAF 6/129 reads (5%) | catalogued as COSV99170210; called by muse, mutect2
- PCIF1 | c.405A>G p.T135= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs746517376, COSV100976080; called by muse, mutect2, varscan2
- PCNT | c.4839G>A p.A1613= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100855632; called by muse, mutect2, varscan2
- PCSK1 | c.1125G>A p.T375= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as rs760792790, COSV100227144, COSV60735197; called by muse, mutect2, varscan2
- PDIA6 | c.618A>G p.E206= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV99694716; called by muse, mutect2, varscan2
- PHC2 | c.960C>T p.H320= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99931144; called by muse, mutect2, varscan2
- PHLPP1 | c.3946C>T p.L1316= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV99408475; called by muse, mutect2, varscan2
- PIGC | c.772C>T p.L258= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV99278245; called by muse, mutect2, varscan2
- PIK3CG | c.1614G>A p.P538= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs1411989310, COSV63247338; called by muse, mutect2, varscan2
- PKD1L2 | c.2277C>A p.A759= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs1386520867, COSV100216700; called by muse, mutect2
- PLCD3 | c.1062C>A p.T354= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100504269; called by muse, mutect2, varscan2
- PLCD4 | c.1485C>A p.S495= | Silent (SNP) | VAF 5/76 reads (7%) | catalogued as COSV101346910; called by muse, mutect2
- PLEKHG2 | c.1033C>T p.L345= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV99216618, COSV99217597; called by muse, mutect2, varscan2
- PLPP5 | c.681C>T p.C227= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV101240681; called by muse, mutect2, varscan2
- PLXNA3 | c.5607C>T p.S1869= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs142629148, COSV100860030; called by muse, mutect2, varscan2
- POTEE | c.789T>C p.A263= | Silent (SNP) | VAF 25/132 reads (19%) | catalogued as COSV100388169; called by muse, mutect2, varscan2
- PQBP1 | c.744A>G p.P248= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99504367; called by muse, mutect2, varscan2
- PRAG1 | c.1002T>C p.A334= | Silent (SNP) | VAF 6/121 reads (5%) | catalogued as COSV100422326; called by muse, mutect2
- PRB2 | c.351G>A p.K117= | Silent (SNP) | VAF 47/157 reads (30%) | catalogued as rs1329751562, COSV101231434; called by muse, mutect2, varscan2
- PRRG2 | c.444G>A p.G148= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs1401890952, COSV99882463; called by mutect2, varscan2
- PRSS21 | c.444C>A p.T148= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV99135587; called by muse, mutect2
- PSD2 | c.1128G>A p.G376= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs898821376, COSV51197919; called by muse, mutect2, varscan2
- PTGDS | c.444C>A p.L148= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV99811907; called by muse, mutect2, varscan2
- R3HDML | c.117G>T p.T39= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV99407174; called by muse, mutect2, varscan2
- RAI1 | c.2073C>T p.S691= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs1184975546, COSV99883254; called by muse, mutect2, varscan2
- RNF19A | c.363C>A p.S121= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100347765, COSV61992404; called by muse, mutect2, varscan2
- RUVBL2 | c.843T>C p.A281= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV99669058; called by muse, mutect2, varscan2
- SAFB | c.240G>A p.E80= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV99385803; called by muse, mutect2, varscan2
- SDR16C5 | c.408C>T p.D136= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs1315680758, COSV100374014; called by mutect2, varscan2
- SEMA3F | c.210C>T p.Y70= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs777707294, COSV99137590; called by mutect2, varscan2
- SH3TC2 | c.657C>T p.G219= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs781321213, COSV100101848; called by muse, mutect2, varscan2
- SHROOM2 | c.3426C>T p.D1142= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs1474026703, COSV66605022; called by muse, mutect2, varscan2
- SLC45A4 | c.1845C>T p.Y615= (on ENST00000517878 / NM_001286646.2; = p.Y564= on NM_001080431.2) | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs1352275230, COSV50201774; called by muse, mutect2, varscan2
- SLC7A13 | c.1023A>G p.L341= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99878966; called by muse, mutect2, varscan2
- SPTBN5 | c.3777C>A p.T1259= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100311637; called by mutect2, varscan2
- SRGAP2 | c.2566C>T p.L856= (on ENST00000624873 / NM_001170637.4; = p.L857= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV99832930; called by muse, mutect2, varscan2
- SRRM2 | c.7860C>T p.S2620= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs776475375, COSV51941774, COSV99241531; called by mutect2, varscan2
- STAB1 | c.7050G>A p.Q2350= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs371825925; called by muse, mutect2, varscan2
- STXBP5L | c.1269G>A p.P423= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs1164709716, COSV56520500; called by muse, mutect2, varscan2
- TGFBR2 | c.1683C>A p.G561= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV55449573; called by muse, mutect2, varscan2
- TLX2 | c.594C>T p.D198= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1234178953, COSV52046311, COSV99283683; called by muse, mutect2, varscan2
- TMC5 | c.1878T>C p.S626= (on ENST00000396229 / NM_001105248.1; = p.S380= on NM_024780.5) | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV99572551; called by muse, mutect2, varscan2
- TMEM220 | c.270A>G p.L90= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100541413; called by muse, mutect2, varscan2
- TMEM79 | c.456C>T p.G152= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as rs771684424, COSV99827964; called by muse, mutect2, varscan2
- TNRC6B | c.2799G>A p.S933= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs370812692; called by muse, mutect2, varscan2
- TPPP3 | c.147C>T p.S49= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs773788525, COSV99339444, COSV99339503; called by muse, mutect2, varscan2
- TRGV9 | c.90C>A p.S30= | Silent (SNP) | VAF 12/55 reads (22%) | called by mutect2, varscan2
- TRH | c.597C>A p.P199= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100234822; called by muse, mutect2, varscan2
- TRIM26 | c.1002C>T p.C334= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs1396875438, COSV70983628; called by muse, mutect2
- TSC1 | c.1059T>C p.C353= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs1216537041, COSV100051959; ClinVar: likely benign; called by muse, mutect2
- TSPAN1 | c.39C>A p.L13= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as COSV100918322, COSV64366429; called by muse, mutect2, varscan2
- ULK3 | c.831T>C p.S277= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV99173968; called by muse, mutect2, varscan2
- UNC13D | c.375C>T p.G125= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV99256923; called by muse, mutect2, varscan2
- UNC45B | c.897G>A p.A299= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs151107152; called by muse, mutect2, varscan2
- USH1G | c.1023G>A p.A341= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs1442592434, COSV100140523, COSV58883064; called by muse, mutect2, varscan2
- WIPI2 | c.462G>A p.T154= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs769371055, COSV56588827, COSV99993412; called by muse, mutect2, varscan2
31 further variants in this file (0 protein-altering or splice-affecting, 12 silent, 19 other) are not listed here.
